Somatic mutation profile of tumor specimen BA3004D (aliquot aq-BA3004D) from BEATAML1.0 case 2420, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.3 years (27,853 days).
Specimen BA3004D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1b015c9-89be-489a-9e93-9b4e0484a947.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2471D (Solid Tissue Normal), aliquot aq-BA2471D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0919fd05-96dd-42fd-9114-040d6bbae3c0

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RFWD3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 3/31 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV63099478; called by muse, mutect2
- TFPI | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51904521; called by muse, mutect2
- FOXJ3 | c.893G>T p.S298I | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PCSK9 | c.2054C>A p.A685E | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- URB2 | c.2643C>A p.D881E | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.031); called by muse, mutect2
- ELFN1 | c.1755C>A p.G585= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV70036447; called by muse, mutect2
- FEZ2 | c.51C>T p.A17= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
